Somatic mutation profile of tumor specimen TCGA-AX-A1CI-01A (aliquot TCGA-AX-A1CI-01A-11D-A135-09) from TCGA case TCGA-AX-A1CI, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G1; Age at diagnosis: 61.8 years (22,582 days).
Specimen TCGA-AX-A1CI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 434c0f12-e589-47a4-8d70-af3c6732310e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A1CI-11A (Solid Tissue Normal), aliquot TCGA-AX-A1CI-11A-11D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c70cc369-4ce7-445a-9967-4d771f7bcac2

The open-access MAF lists 39 somatic variants for this specimen: 31 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 6, Frame Shift Ins 2, Splice Region 1, Frame Shift Del 1, Intron 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 22/27 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434592, COSV62571334, COSV62576849; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.6259G>A p.G2087R | Missense Mutation (SNP) | VAF 15/25 reads (60%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1553153748, COSV61371196, COSV61381160; ClinVar: other; called by muse, mutect2, varscan2
- CTNNB1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: other / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.512T>C p.I171T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.83); PolyPhen benign (0.033); catalogued as rs1192934631; called by muse, mutect2, varscan2
- BEND3 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs782223733; called by muse, mutect2, varscan2
- CTCF | c.781+2T>C p.X261_splice | Splice Site (SNP) | VAF 6/10 reads (60%) | catalogued as COSV50462206, COSV50472021; called by muse, mutect2, varscan2
- DNAH5 | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.009); catalogued as COSV54215854; called by muse, mutect2, varscan2
- INPPL1 | c.2720G>A p.R907Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs933270129, COSV53353088; called by muse, mutect2, varscan2
- INTS3 | c.1111C>T p.R371W | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1173195913; called by muse, mutect2, varscan2
- KRT72 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs755309278, COSV99537102; called by muse, mutect2, varscan2
- NCOA7 | c.2314G>A p.V772M | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.17); catalogued as rs1235048293; called by muse, mutect2, varscan2
- PRPSAP2 | c.244G>A p.V82M | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs765950480, COSV52066330; called by muse, mutect2, varscan2
- RBL1 | c.2308A>G p.K770E | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.01); catalogued as rs754070719; called by muse, mutect2, varscan2
- SBF1 | c.2350G>A p.G784R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as rs368432657; called by muse, mutect2, varscan2
- SORCS2 | c.1303C>T p.R435W | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs763678557; called by muse, varscan2
- SSUH2 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs144078609; called by muse, mutect2, varscan2
- SYNPO2 | c.1984G>A p.D662N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.51); catalogued as rs759797608, COSV61116874; called by muse, mutect2, varscan2
- TRPC7 | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775748277, COSV61452609; called by muse, mutect2, varscan2
- ANKDD1A | c.688C>A p.H230N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- CDSN | c.452G>A p.S151N | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CEP78 | c.1015_1019delinsT p.R339* | Frame Shift Del (DEL) | VAF 19/38 reads (50%) | called by pindel, varscan2*
- CHD6 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- CLU | c.50G>A p.S17N | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- HUWE1 | c.643dup p.R215Kfs*4 | Frame Shift Ins (INS) | VAF 4/31 reads (13%) | called by pindel, varscan2
- KIF13B | c.2339T>G p.I780R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MUC16 | c.32001C>A p.F10667L | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PLK2 | c.1250_1251dup p.E418Mfs*19 | Frame Shift Ins (INS) | VAF 49/110 reads (45%) | called by mutect2, pindel, varscan2
- RICTOR | c.409C>A p.Q137K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- SLC22A12 | c.1307C>T p.A436V | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.58); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- STAC | c.111G>A p.K37= | Splice Region (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- ZNF613 | c.1642A>T p.N548Y (on ENST00000293471 / NM_001031721.4; = p.N512Y on NM_024840.4) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADGRA2 | c.1839C>T p.S613= | Silent (SNP) | VAF 16/116 reads (14%) | catalogued as rs762301019; called by muse, mutect2, varscan2
- ECEL1 | c.1482G>A p.E494= | Silent (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
- ERF | c.942G>T p.L314= | Silent (SNP) | VAF 15/25 reads (60%) | catalogued as COSV99724429; called by muse, varscan2
- FGFR4 | c.375C>T p.N125= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as rs184093905; called by muse, mutect2, varscan2
- FRYL | c.183C>T p.S61= | Silent (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- NLGN4X | c.1167T>C p.G389= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99319512; called by muse, mutect2, varscan2
- CARD16 | c.274+863T>A | Intron (SNP) | VAF 14/31 reads (45%) | catalogued as COSV100995065; called by muse, mutect2, varscan2
- SNORD3A | n.49T>G | RNA (SNP) | VAF 15/199 reads (8%) | catalogued as rs766793410; called by muse, mutect2
